Somatic mutation profile of tumor specimen TARGET-40-PAVPHS-01A (aliquot TARGET-40-PAVPHS-01A-01D) from TARGET case TARGET-40-PAVPHS, project TARGET-OS (Osteosarcoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Osteosarcoma, NOS; Tissue or organ of origin: Long bones of lower limb and associated joints; Age at diagnosis: 9.1 years (3,340 days).
Specimen TARGET-40-PAVPHS-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 8adf2c41-2c5a-4f29-abb5-a30e0b22672f.targeted_sequencing.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-40-PAVPHS-10A (Blood Derived Normal), aliquot TARGET-40-PAVPHS-10A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/05d6577c-bee1-40dc-8efa-cffa2a0d8c00

The open-access MAF lists 6 somatic variants for this specimen: 5 protein-altering or splice-affecting, 1 silent.
By variant classification: Missense Mutation 5, Silent 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- DMD | c.8473G>A p.D2825N | Missense Mutation (SNP) | VAF 16/45 reads (36%) | SIFT tolerated (0.27); PolyPhen benign (0.007); catalogued as rs893710763, CD159995, COSV58891024; called by muse, varscan2
- KIAA1549L | c.527C>G p.S176C (on ENST00000321505; = p.S473C on NM_012194.3) | Missense Mutation (SNP) | VAF 6/52 reads (12%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.436); called by mutect2, varscan2
- MYH14 | c.454C>G p.P152A | Missense Mutation (SNP) | VAF 10/59 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- TTN | c.21134A>T p.K7045I (on ENST00000591111; = p.K6118I on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 27/51 reads (53%) | PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- ZFHX3 | c.1054G>C p.V352L | Missense Mutation (SNP) | VAF 4/24 reads (17%) | SIFT tolerated (0.25); PolyPhen possibly damaging (0.531); called by mutect2, varscan2
- DMD | c.8688A>G p.R2896= | Silent (SNP) | VAF 4/26 reads (15%) | called by muse, mutect2
